Somatic mutation profile of tumor specimen C3L-02220-01 (aliquot CPT0104550009) from CPTAC case C3L-02220, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 72.6 years (26,508 days).
Specimen C3L-02220-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 330d7bed-afe2-4d2f-9210-7960c860fc67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02220-31 (Blood Derived Normal), aliquot CPT0105170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4f36388-f9fb-4b47-a535-33e5561d1b6f

The open-access MAF lists 79 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Frame Shift Del 9, Splice Site 3, Nonsense Mutation 2, In Frame Del 2, Intron 2, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4366T>G p.W1456G | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1085307114, COSV63868407; ClinVar: pathogenic; called by muse, mutect2
- ACP5 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 79/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185723918, COSV54536864; called by muse, mutect2, varscan2
- CLEC17A | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100355339; called by muse, mutect2, varscan2
- DCP1B | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV54967885; called by muse, mutect2, varscan2
- DENND1C | c.1352T>C p.M451T | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs1280378893; called by muse, mutect2, varscan2
- F3 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1340379553; called by muse, mutect2, varscan2
- FOXA1 | c.1205T>G p.I402S | Missense Mutation (SNP) | VAF 18/429 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51649855; called by muse, mutect2
- HGSNAT | c.1543G>T p.G515W | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52816140; called by muse, mutect2, varscan2
- LRRC58 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs770871284; called by muse, mutect2, varscan2
- LUZP1 | c.2909T>A p.L970H | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.639); catalogued as rs775645953; called by muse, mutect2, varscan2
- MTHFD1L | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1257266984; called by muse, mutect2, varscan2
- MYO15A | c.3308G>A p.G1103E | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs750304417; called by muse, mutect2, varscan2
- OR5D16 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101003880, COSV65722143; called by muse, mutect2, varscan2
- OR9A2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV63307061; called by muse, mutect2
- PAX2 | c.1207dup p.R403Pfs*13 (on ENST00000428433 / NM_003987.5; = p.R380Pfs*13 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 54/355 reads (15%) | catalogued as rs750453189; called by pindel, varscan2
- PCDHB11 | c.648T>G p.D216E | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782507853; called by muse, mutect2
- RPS10-NUDT3 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 78/396 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV58241886; called by muse, mutect2, varscan2
- RPS14 | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs758244627; called by muse, mutect2, varscan2
- UNC13D | c.1055+1G>A p.X352_splice | Splice Site (SNP) | VAF 24/508 reads (5%) | catalogued as rs754205110, CS113891, COSV52884856; called by muse, mutect2
- AASDHPPT | c.540_542del p.E181del | In Frame Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel
- ACADL | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by mutect2, varscan2
- ARHGAP4 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, varscan2
- ARSJ | c.457T>G p.L153V | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP1A4 | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 101/466 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ATP6AP1 | c.342C>G p.D114E | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- BCLAF1 | c.1754del p.F585Sfs*42 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- CD2BP2 | c.118_122del p.R40* | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | called by mutect2, pindel, varscan2
- FAM135B | c.3541_3553del p.M1181Qfs*6 | Frame Shift Del (DEL) | VAF 17/141 reads (12%) | called by mutect2, pindel
- FAM184B | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- FAM186B | c.1905del p.P636Lfs*10 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- FCGBP | c.6263del p.F2088Sfs*11 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- GABBR1 | c.1337T>A p.F446Y | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, varscan2
- GMPS | c.1195A>T p.R399* | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- HIVEP3 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HMCN1 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.13971G>T p.Q4657H | Missense Mutation (SNP) | VAF 30/624 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- KCNH8 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LATS1 | c.2170A>C p.K724Q | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MECOM | c.1006del p.S336Vfs*6 (on ENST00000468789 / NM_001105078.4; = p.S524Vfs*6 on NM_004991.4) | Frame Shift Del (DEL) | VAF 74/460 reads (16%) | called by pindel, varscan2
- MEIOB | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MYLIP | c.229A>G p.R77G | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, varscan2
- NANOG | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- NTM | c.356C>G p.T119R | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2A1 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 66/660 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OSTF1 | c.290_291del p.V97Gfs*3 | Frame Shift Del (DEL) | VAF 32/204 reads (16%) | called by pindel, varscan2
- PBRM1 | c.2125del p.I709Ffs*5 | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | called by mutect2, pindel, varscan2
- PKN1 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PRSS53 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RECK | c.1445C>A p.T482N | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RNF112 | c.720+2_720+7del p.X240_splice | Splice Site (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- SAMHD1 | c.1270+1G>T p.X424_splice | Splice Site (SNP) | VAF 84/402 reads (21%) | called by muse, mutect2, varscan2
- SH2D3C | c.296_302del p.E99Vfs*23 | Frame Shift Del (DEL) | VAF 66/281 reads (23%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC39A3 | c.322_323dup p.R109Sfs*50 | Frame Shift Ins (INS) | VAF 48/255 reads (19%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1820_1822del p.L607_E608delinsQ | In Frame Del (DEL) | VAF 41/190 reads (22%) | called by mutect2, pindel, varscan2
- SSH1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- STOX1 | c.1570A>G p.T524A | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- THOC2 | c.4522G>A p.G1508R | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- TNFSF13 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTPAL | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TTYH1 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- USH1C | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRI3BP | c.567C>T p.C189= | Silent (SNP) | VAF 9/237 reads (4%) | called by muse, mutect2
- CFAP46 | c.2352G>A p.V784= | Silent (SNP) | VAF 43/201 reads (21%) | called by muse, mutect2, varscan2
- DROSHA | c.24C>T p.H8= | Silent (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- EXOSC1 | c.258C>T p.H86= | Silent (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- GABRA5 | c.621C>T p.N207= | Silent (SNP) | VAF 59/259 reads (23%) | catalogued as rs200310381; called by muse, mutect2
- HSF2 | c.813T>C p.V271= | Silent (SNP) | VAF 54/246 reads (22%) | called by muse, mutect2, varscan2
- LTBP1 | c.4131C>A p.G1377= (on ENST00000404816 / NM_206943.4; = p.G1051= on NM_000627.4) | Silent (SNP) | VAF 60/230 reads (26%) | called by muse, mutect2, varscan2
- MED13 | c.1710T>G p.V570= | Silent (SNP) | VAF 28/203 reads (14%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.591C>A p.V197= | Silent (SNP) | VAF 30/435 reads (7%) | catalogued as COSV57107155; called by muse, mutect2
- PCDHGB3 | c.1479C>T p.A493= | Silent (SNP) | VAF 99/580 reads (17%) | called by muse, mutect2, varscan2
- PDZD2 | c.5649G>A p.P1883= | Silent (SNP) | VAF 10/242 reads (4%) | catalogued as rs900170628; called by muse, mutect2
- SRCAP | c.1020C>G p.P340= | Silent (SNP) | VAF 71/400 reads (18%) | catalogued as rs200460366, COSV99348959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM120A | c.735C>G p.L245= | Silent (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- TOGARAM2 | c.2055T>C p.T685= | Silent (SNP) | VAF 60/287 reads (21%) | called by muse, mutect2, varscan2
- ABR | c.1961+284G>A | Intron (SNP) | VAF 34/175 reads (19%) | catalogued as rs1011825343; called by muse, mutect2, varscan2
- FAM205BP | n.932C>T | RNA (SNP) | VAF 88/437 reads (20%) | called by muse, mutect2, varscan2
- NRG3 | c.824-191962del | Intron (DEL) | VAF 41/183 reads (22%) | called by mutect2, pindel, varscan2
